Somatic mutation profile of tumor specimen TCGA-R8-A6ML-01A (aliquot TCGA-R8-A6ML-01A-11D-A32B-08) from TCGA case TCGA-R8-A6ML, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.5 years (19,185 days).
Specimen TCGA-R8-A6ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80c41cf-7645-4235-a534-869c9ca6d34f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R8-A6ML-10A (Blood Derived Normal), aliquot TCGA-R8-A6ML-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb93a7c-1fb0-4891-ad61-6ec68a9717ef

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53091312; called by muse, mutect2
- CFAP44 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs370318076; called by muse, mutect2, varscan2
- CIC | c.2735dup p.G913Wfs*18 | Frame Shift Ins (INS) | VAF 110/216 reads (51%) | catalogued as COSV50560113; called by mutect2, pindel, varscan2
- CRYBA1 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99837066; called by muse, mutect2, varscan2
- F12 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99499533; called by muse, mutect2
- FAM167B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747746477, COSV61107373; called by muse, mutect2, varscan2
- FAM71A | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs201312997, COSV54237337; called by muse, mutect2, varscan2
- ITIH6 | c.2605A>G p.I869V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99513767; called by muse, mutect2, varscan2
- MEGF11 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757871149, COSV99988776; called by muse, mutect2, varscan2
- NHLRC1 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100513526; called by muse, mutect2, varscan2
- RBM28 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.965); catalogued as rs781569084, COSV99775600, COSV99775857; called by muse, mutect2, varscan2
- SGO2 | c.2572G>T p.V858F | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs777601547, COSV100764757; called by muse, mutect2, varscan2
- SLIT2 | c.2867T>C p.V956A | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99886218; called by muse, mutect2, varscan2
- SMC1A | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100447621, COSV59131839; called by muse, mutect2, varscan2
- SSMEM1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927813; called by muse, mutect2, varscan2
- NIPBL | c.8_18del p.G3Afs*12 | Frame Shift Del (DEL) | VAF 11/130 reads (8%) | called by mutect2, pindel
- KRT25 | c.1008G>A p.A336= | Silent (SNP) | VAF 129/327 reads (39%) | catalogued as rs1459792230, COSV100379925, COSV56443491; called by muse, mutect2, varscan2
- SEMA3G | c.1140C>T p.G380= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs768111641, COSV99202549; called by muse, varscan2
- WDR27 | c.2268C>T p.F756= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV61215875; called by muse, mutect2, varscan2
